Gene-level copy-number profile of tumor specimen TCGA-25-1317-01A from TCGA case TCGA-25-1317, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.3 years (24,199 days).
Specimen TCGA-25-1317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bd6da330-a14d-424a-8bb6-ac244273969e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1317-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74c2debf-75eb-4a9a-97ce-71f0d227c01e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,569; copy number 2: 19,029; copy number 3: 17,305; copy number 4: 16,655; copy number 5: 4,211; copy number 7: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1317-01): tumor purity 0.77, ploidy 3.08, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,262 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–240,776,824, 47 genes, copy number 5: AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,823,433, 1 gene, copy number 5: RFKP1.
- chr2:75,799,974–84,040,720, 70 genes, copy number 5 (broad region; genes not listed).
- chr6:71,126,893–76,092,940, 90 genes, copy number 5 (broad region; genes not listed).
- chr6:77,343,557–79,537,458, 21 genes, copy number 7 (within-gene range 2–7): AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5.
- chr8:35,235,475–145,066,685, 1,726 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–38,762,491, 674 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–21,206,900, 175 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
